Surgical pathology report (de-identified scan), TCGA case TCGA-CJ-4908, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CJ-4908-01A (Primary Tumor).

Surgery Date: [REDACTED]

TCGA-CJ-4908

Pathology Report

DIAGNOSIS

(A) RIGHT KIDNEY:

RENAL CELL CARCINOMA, CONVENTIONAL (CLEAR CELL TYPE), FUHRMAN'S NUCLEAR GRADE 2.

TUMOR CONFINED TO KIDNEY.

TUMOR MEASURES 3.9 CM IN GREATEST DIMENSION.

Vascular, ureteral and soft tissue margins of resection free of tumor.

Renal cortical adenoma (0.2 cm).

Renomedullary interstitial cell tumor (0.3 cm).

GROSS DESCRIPTION

(A) RIGHT KIDNEY - A nephrectomy specimen (18.0 x 12.0 x 6.0 cm) including the right kidney (12.0 x 7.0 x 4.5 cm), a segment of the renal artery, the renal vein and ureter (10.0 cm in length and 0.4 cm in average diameter).

There is a 3.9 x 3.5 x 3.5 cm well-circumscribed tumor in the mid pole of the kidney. The tumor is yellow-tan with extensive areas of hemorrhage, which are present predominantly in the center of the tumor. The tumor is confined to the kidney. The tumor does not invade into the perinephric adipose tissue, renal sinus or renal vein. The tumor does not extend to Gerota's fascia.

The adjacent kidney parenchyma is unremarkable. The pelvicalyceal system is smooth and devoid of any lesions. No lymph nodes are identified in the hilum of the kidney.

Portions of the tumor have been submitted for possible electron microscopy and tumor bank.

INK CODE: Black - Gerota's fascia.

SECTION CODE: A1, ureter, renal artery and renal vein margin; A2-A4, tumor and renal sinus; A5-A7, tumor and adjacent kidney; A8-A10, tumor and perinephric adipose tissue; A11, A12, non-neoplastic kidney. [REDACTED]

CLINICAL HISTORY

Mass right kidney.

SNOMED CODES

T-71000, M-83123, M-Y1640

Source: NCI Genomic Data Commons file aaf26a4f-1f54-4f0d-9431-ed501ef88416 (TCGA-CJ-4908.DA7D2C64-4CBF-472A-A496-CAEC27CE148A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).